Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A45Z, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A45Z-01A (Primary Tumor).

[page 1 of 2]
DOB

Sex: M

Physician:

Received:

Pathologist:

Accession:

Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to section "SPECIMEN" may have been added. ****

DIAGNOSIS

- (A) RIGHT FALSE CORD:
INVASIVE SQUAMOUS CARCINOMA.
- (B) NOSE RIGHT PAROTID BULB:
Lymph node, no tumor.
- (C) RIGHT THYROID LOBECTOMY:
Multinodular goiter.
- (D) LARYNGECTOMY:

100-0-3

Carcinoma, squamous cell, NOS 807013
site: larynx, NOS C32.9

10/1/12

SQUAMOUS CARCINOMA, GRADE 3 WITH LYMPHATIC INVASION INVOLVING RIGHT AND LEFT SUPRAGLOTTIC REGIONS. MARGINS OF RESECTION FREE, THICKNESS OF THE TUMOR, 1.2 CM. SQUAMOUS CARCINOMA IN SITU IN RIGHT VENTRICLE. Large tracheal margin of resection free of tumor. Seven right cervical lymph nodes, no tumor. Two cervical lymph nodes, no tumor.

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION

(A) RIGHT FALSE CORD - Three fragments of tan-pink tissue admixed with blood clot (overall 0.5 x 0.4 x 0.2 cm). Entirely submitted for frozen section in A.

~FS/DX: SQUAMOUS CELL CARCINOMA, INVASIVE.

(B) NODE, RIGHT PAROTID BULB - A lymph node, 1.5 x 0.6 x 0.7 cm. Bisected in toto in B.

(C) RIGHT THYROID LOBECTOMY - A right lobe of the thyroid (5.0 x 3.0 x 1.7 cm), with several nodules, ranging from 0.2 to 1.1 cm. A more preserved portion of thyroid tissue is at the superior aspect, it is red-brown and meaty; the nodules range from red to light brown color. The specimen sampled for frozen section in C1 and C2; representative sections are submitted in C3-C6.

INK CODE: Yellow - isthmus margin; blue - thyroid surface.

(D) LARYNGECTOMY - A laryngectomy and attached soft tissue and lymph node dissection with overall measurements of 8.0 x 6.0 x 5.0 cm. A light tan indurated and ulcerated lesion located in the right supraglottic area and extending to the midline approximately 0.5 cm into the left supraglottic area is 2.0 x 1.5 x 1.0 cm mass. The mucosal and external surfaces specimen are uninvolved grossly by tumor. The specimen is submitted sequentially from right to left.

SECTION CODE: D1-D17, lymph nodes, right; D18-D19, lymph nodes, left.

[page 2 of 2]
DOB:
Physician:

Sex: M

Received

Pathologist:
Case type: Surgical History

Accession:

*FS/DX: MUCOSA, NO TUMOR PRESENT.

ADDITIONAL STUDIES

PHOTO: (A) LARYNX

SNOMED CODES

M-80703 T-24455

Qual/Synch: cncs Primary Noted		☒

fw
9/9/12

Page 2 of 2

History Case Pathology Report
File under: Pathology

History Case Pathology

Source: NCI Genomic Data Commons file 6a597222-44f9-4409-90cd-82e65413b33d (TCGA-CV-A45Z.51863920-F05E-4757-A98E-77CFBB6D1130.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).